Gene-level copy-number profile of tumor specimen TCGA-OR-A5JW-01A from TCGA case TCGA-OR-A5JW, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 47.9 years (17,513 days).
Specimen TCGA-OR-A5JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.8cb9f38a-147a-47d0-a631-a1a1cca4c118.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/137bb84e-64ca-432b-ac51-729b99810e81

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 28,124; copy number 3: 35; copy number 4: 29,064; copy number 5: 3; copy number 6: 2,483; copy number 7: 1; copy number 8: 91; copy number 9: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JW-01A-11D-A29H-01): tumor purity 0.88, ploidy 1.6, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,892,188–21,995,301, 4 genes (within-gene range 0–4): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr22:29,058,672–29,061,844, 1 gene: C22orf31.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:25,909,503–26,484,711, 5 genes, copy number 9: MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr5:29,600,676–30,693,984, 9 genes, copy number 9 (within-gene range 4–9): UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
